Somatic mutation profile of tumor specimen TCGA-XJ-A9DX-01A (aliquot TCGA-XJ-A9DX-01A-11D-A377-08) from TCGA case TCGA-XJ-A9DX, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-XJ-A9DX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a255177-f562-4924-90e5-e567fb0eed0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XJ-A9DX-10A (Blood Derived Normal), aliquot TCGA-XJ-A9DX-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6234aa29-f1fd-4bc3-bd1d-7feaa9f4413b

The open-access MAF lists 63 somatic variants for this specimen: 53 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 42, Silent 10, Frame Shift Ins 4, Frame Shift Del 3, Nonsense Mutation 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL10 | c.187G>C p.A63P | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV99865182; called by muse, mutect2
- ACTL8 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.769); catalogued as rs773088483, COSV100958701, COSV100958734, COSV100958806; called by muse, mutect2, varscan2
- ADCY2 | c.3200G>A p.G1067E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100604182; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1124G>A p.R375K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV99314524; called by muse, mutect2, varscan2
- B3GALT2 | c.448A>G p.S150G | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100813640; called by muse, mutect2, varscan2
- CLDN23 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101093190; called by muse, mutect2, varscan2
- CNTNAP1 | c.184T>A p.S62T | Missense Mutation (SNP) | VAF 57/112 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs745452887, COSV99227042; called by muse, mutect2, varscan2
- CRB2 | c.2507A>C p.N836T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV63502540; called by muse, mutect2, varscan2
- DCN | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.545); catalogued as COSV99272806; called by muse, mutect2, varscan2
- DSC1 | c.1521G>T p.R507S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.433); catalogued as rs1261109112, COSV99938296; called by muse, mutect2, varscan2
- ECPAS | c.189A>G p.I63M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV99399355; called by muse, mutect2, varscan2
- ESYT1 | c.2337G>A p.E779= | Splice Region (SNP) | VAF 19/64 reads (30%) | catalogued as COSV99920326; called by muse, mutect2, varscan2
- EXOC6B | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99726530; called by muse, mutect2, varscan2
- FGFR1 | c.2350C>T p.R784W (on ENST00000447712 / NM_023110.3; = p.R782W on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377149398; called by muse, mutect2, varscan2
- FGR | c.1307C>A p.T436N | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100925815; called by muse, mutect2, varscan2
- FZD6 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 26/125 reads (21%) | catalogued as COSV100708499; called by muse, mutect2, varscan2
- HELLS | c.441T>G p.I147M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); catalogued as COSV99492428; called by muse, mutect2, varscan2
- HORMAD1 | c.646_647del p.S216Nfs*13 | Frame Shift Del (DEL) | VAF 66/151 reads (44%) | catalogued as rs1192919608; called by pindel, varscan2
- IGF2 | c.679G>A p.A227T (on ENST00000434045 / NM_001127598.3; = p.A171T on NM_000612.6) | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1347870712, COSV100324250, COSV56099895; called by muse, mutect2, varscan2
- IL6ST | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100411060; called by muse, mutect2, varscan2
- IL6ST | c.1244C>T p.T415I | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV61143299; called by muse, mutect2, varscan2
- KDM3B | c.2473G>T p.E825* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as COSV100070254; called by muse, mutect2
- LHX8 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV99634435; called by muse, varscan2
- LNPEP | c.2767A>T p.K923* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as COSV99183625; called by muse, mutect2, varscan2
- LRATD1 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as rs1391788796, COSV99707293; called by muse, mutect2, varscan2
- MARCHF1 | c.423G>T p.K141N (on ENST00000274056; = p.K124N on NM_017923.4) | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as COSV99922627; called by muse, mutect2, varscan2
- MKRN1 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.603); catalogued as COSV99751904; called by muse, mutect2, varscan2
- MMRN1 | c.2939C>T p.S980F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1173222412, COSV99307783; called by muse, mutect2, varscan2
- MOV10 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62493085; called by muse, mutect2, varscan2
- PACSIN1 | c.1158G>C p.K386N | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as COSV55058577, COSV99763359; called by muse, mutect2, varscan2
- RAVER1 | c.899G>C p.G300A | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as rs1319104742, COSV99533161; called by muse, mutect2, varscan2
- RETSAT | c.1004G>T p.S335I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV99806298; called by muse, mutect2, varscan2
- SACS | c.8188C>A p.L2730M | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV101207253, COSV101207741; called by muse, mutect2, varscan2
- SART3 | c.1120C>G p.R374G (on ENST00000228284; = p.R356G on NM_014706.4) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.758); catalogued as COSV57205123, COSV99934455; called by muse, mutect2, varscan2
- SIPA1L3 | c.3616G>A p.G1206S | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as rs1437307234, COSV55922680; called by muse, mutect2, varscan2
- SLC17A8 | c.713C>A p.A238D | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100035888; called by muse, mutect2, varscan2
- SNRPB2 | c.173A>G p.E58G | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99855914; called by muse, mutect2, varscan2
- SUPT20H | c.587A>G p.E196G (on ENST00000350612 / NM_001014286.3; = p.E197G on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100634823; called by muse, mutect2, varscan2
- TAS2R43 | c.760A>C p.S254R | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101115635; called by mutect2, varscan2
- TASOR2 | c.4486C>T p.P1496S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs1051054476, COSV100051092; called by muse, mutect2, varscan2
- TCHHL1 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); catalogued as COSV100916618; called by muse, mutect2
- TNFRSF21 | c.1853T>C p.I618T | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV99730268; called by muse, mutect2
- TOP3A | c.2231T>C p.L744P | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs564388683, COSV100329323; called by muse, mutect2, varscan2
- VPS13D | c.10957A>G p.T3653A | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV50656983; called by muse, mutect2
- ZBED2 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.011); catalogued as COSV51920303; called by muse, mutect2, varscan2
- ZNF148 | c.721C>A p.H241N | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV100642182, COSV62304579; called by muse, mutect2, varscan2
- ZNF345 | c.1307A>T p.Y436F | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs1393426844, COSV100080456; called by muse, mutect2, varscan2
- ANO2 | c.2434dup p.I812Nfs*57 (on ENST00000356134 / NM_001278597.3; = p.I816Nfs*57 on NM_001278596.3) | Frame Shift Ins (INS) | VAF 23/78 reads (29%) | called by mutect2, pindel, varscan2
- OR10G3 | c.727_730dup p.A244Gfs*22 | Frame Shift Ins (INS) | VAF 18/61 reads (30%) | called by mutect2, pindel, varscan2
- PIK3CD | c.2109_2110del p.Q704Efs*39 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | called by pindel, varscan2
- RABGAP1 | c.3120dup p.E1041* | Frame Shift Ins (INS) | VAF 20/47 reads (43%) | called by mutect2, pindel, varscan2
- TPTE | c.1538dup p.N513Kfs*2 (on ENST00000618007 / NM_199261.4; = p.N495Kfs*2 on NM_199259.4) | Frame Shift Ins (INS) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- ZNF324 | c.1520del p.K507Rfs*58 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- AHRR | c.1017T>C p.T339= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV100328015, COSV57091088; called by muse, mutect2, varscan2
- BCKDK | c.813C>T p.Y271= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99570886; called by muse, mutect2, varscan2
- BSN | c.11190C>T p.S3730= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as rs367558667; called by muse, mutect2, varscan2
- CSN2 | c.630C>A p.I210= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV61991986, COSV61992257; called by muse, mutect2, varscan2
- HEATR5A | c.5556C>T p.I1852= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV101120570; called by muse, mutect2, varscan2
- LCK | c.1026G>A p.L342= | Silent (SNP) | VAF 81/258 reads (31%) | catalogued as COSV100288176; called by muse, mutect2, varscan2
- PRPF18 | c.924C>T p.D308= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs767908291, COSV60726188; called by muse, mutect2, varscan2
- SHROOM1 | c.1137T>C p.P379= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV100167297; called by muse, mutect2, varscan2
- SLIT3 | c.3390C>T p.N1130= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs745348925, COSV100270044; called by muse, mutect2, varscan2
- SLITRK2 | c.447C>T p.I149= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as rs782263203, COSV100158226, COSV59428987; called by muse, mutect2, varscan2
